Gene-level copy-number profile of tumor specimen TCGA-DX-A6YU-01A from TCGA case TCGA-DX-A6YU, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Fibromyxosarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of thorax; Age at diagnosis: 50.2 years (18,351 days).
Specimen TCGA-DX-A6YU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.dd87231a-d658-43b1-ace0-e43c41832718.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DX-A6YU-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 821 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/35234fc5-4f91-4b88-996c-03a3e909b599

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 34; copy number 1: 1,810; copy number 2: 19,793; copy number 3: 11,805; copy number 4: 16,696; copy number 5: 5,992; copy number 6: 3,484; copy number 7: 6; copy number 8: 43; copy number 10: 24; copy number 11: 115.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DX-A6YU-01A-12D-A33D-01): tumor purity 0.51, ploidy 3.24, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 34 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:150,584–545,781, 17 genes: AC131281.2, WBP1LP3, OR4F21, SEPTIN14P8, AC131281.1, RPL23AP53, ZNF596, AC004908.2, AC004908.1, AC004908.3, AC136777.2, AC136777.1, FAM87A, FBXO25, AC083964.1, AC083964.2, TDRP.
- chr13:48,232,612–48,599,436, 8 genes (within-gene range 0–2): ITM2B, RB1-DT, RB1, PPP1R26P1, PCNPP5, AL392048.1, LPAR6, Metazoa_SRP.
- chr18:80,034,346–80,097,088, 1 gene (within-gene range 0–2): AC090360.1.
- chr18:80,046,900–80,247,514, 7 genes (within-gene range 0–2): RBFADN, SLC25A6P4, ADNP2, PARD6G-AS1, PARD6G, AC139100.2, AC139100.1.
- chr20:24,491,472–24,502,345, 1 gene: AL157413.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 9,005 genes in 27 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:38,814–209,892, 2 genes, copy number 5: FAM110C, AC079779.1.
- chr2:94,725,674–130,441,413, 713 genes, copy number 5 (broad region; genes not listed).
- chr4:51,843,000–55,125,595, 59 genes, copy number 8–10 (within-gene range 2–10): DCUN1D4, DUTP7, AC027271.1, AC104784.1, LRRC66, SGCB, LINC02480, SPATA18, AC097522.2, AC097522.1, RNU6-1252P, USP46, USP46-DT, AC104066.3, DANCR, LINC01618, MIR4449, AC104066.4, SNORA26, AC104066.2, ERVMER34-1, AC104066.1, Y_RNA, RASL11B, SCFD2, AC023154.1, RNU6-310P, FIP1L1, AC058822.1, LNX1, LNX1-AS1, AC095040.1, LNX1-AS2, AC124017.1, AC105384.1, AC105384.2, RPL21P44, AC110792.3, CHIC2, AC110792.2, AC110792.4, AC110792.1, MORF4L2P1, GSX2, RPL22P13, PDGFRA, LINC02283, AC098587.1, AC098868.1, LINC02260, KIT, AC097494.1, LINC02358, AC111194.1, RPL38P3, RNU6-410P, AC111194.2, RN7SL424P, KDR.
- chr4:58,103,147–59,180,414, 10 genes, copy number 7–8: SRIP1, AC096725.1, LINC02494, AC019133.1, AC017091.1, LINC02619, LINC02429, AC097501.1, AC108517.2, AC108517.1.
- chr4:106,315,544–106,938,640, 5 genes, copy number 5: AIMP1, GIMD1, LINC02173, AC092445.1, ACTR6P1.
- chr5:21,341,833–43,280,850, 314 genes, copy number 6 (within-gene range 3–6) (broad region; genes not listed).
- chr5:43,287,601–43,290,839, 1 gene, copy number 6: AC114947.2.
- chr5:92,654,848–148,442,836, 961 genes, copy number 5–6 (broad region; genes not listed).
- chr6:167,607–4,703,779, 106 genes, copy number 5 (broad region; genes not listed).
- chr6:4,714,098–4,775,408, 2 genes, copy number 5: AL356747.1, CDYL-AS1.
- chr6:95,504,182–166,956,124, 1,036 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr7:549,197–62,275,678, 1,059 genes, copy number 6 (broad region; genes not listed).
- chr9:60,914,407–119,974,322, 982 genes, copy number 6 (broad region; genes not listed).
- chr9:122,798,389–122,828,588, 1 gene, copy number 5 (within-gene range 3–5): PDCL.
- chr9:122,837,557–127,223,166, 84 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr11:21,799,934–22,338,245, 5 genes, copy number 5 (within-gene range 2–5): ANO5, AC116534.1, AC107882.1, AC107886.1, AC104009.1.
- chr11:25,140,533–25,141,023, 1 gene, copy number 5: AC087373.1.
- chr16:2,275,881–30,822,110, 915 genes, copy number 5–6 (within-gene range 3–6) (broad region; genes not listed).
- chr17:15,699,577–22,706,703, 366 genes, copy number 5–11 (broad region; genes not listed).
- chr18:65,105,873–70,205,726, 50 genes, copy number 5 (within-gene range 4–5): AC007948.1, AC007631.1, LINC01916, AC090358.1, CDH7, AC023394.2, AC023394.1, PRPF19P1, CDH19, RNU6-1037P, MIR5011, RPL31P9, AC091042.1, AC110597.1, DSEL, AC110597.3, AC114689.3, AC022662.1, AC022655.1, FAM32DP, AC114689.1, LINC01903, AC114689.2, AC100844.1, AC068112.1, AC005909.2, LINC01912, AC022968.1, AC005909.1, AKR1B10P2, MTL3P, TMX3, CCDC102B, AC040896.1, AC022035.1, RNU6-39P, SDHCP1, AC096708.2, AC096708.3, AC096708.1, AC090337.1, AC090337.2, AC026585.1, DOK6, AC119868.1, AC119868.2, AC068254.2, AC068254.1, CD226, RTTN.
- chr18:71,000,477–74,160,531, 28 genes, copy number 5: AC090415.2, AC090415.1, AC091691.3, AC091691.2, AC091691.1, LINC01541, AC090312.1, AC090312.2, LINC01899, AC027458.1, AC069114.1, AC069114.2, CBLN2, HNRNPA1P11, NETO1, AC023301.1, RNA5SP460, MIR548AV, AC091138.1, LINC02864, LINC02582, AC079070.1, RN7SL401P, AC090125.1, AC010947.1, AC090125.2, FBXO15, TIMM21.
- chr19:28,065,267–58,605,223, 1,672 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr20:4,192,932–4,591,300, 5 genes, copy number 5: LINC01433, ADRA1D, AL139350.1, AL121781.1, AL121916.1.
- chr20:12,865,202–13,008,417, 4 genes, copy number 7: LINC01722, AL078623.1, AL133331.1, LINC01723.
- chr20:13,995,369–16,053,197, 1 gene, copy number 6 (within-gene range 4–6): MACROD2.
- chr20:14,884,250–16,573,448, 11 genes, copy number 6 (within-gene range 4–6): MACROD2-AS1, AL138808.1, RNU6-1159P, RNU6-115P, RNA5SP475, AL121584.1, ENSAP1, AL079338.1, AL161941.1, PPIAP17, KIF16B.
- chr21:16,862,875–45,625,675, 612 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 802. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
